Somatic mutation profile of tumor specimen CDDP-A8B5-TTP1-C (aliquot CDDP-A8B5-TTP1-C-1-0-D-A500-36) from CDDP_EAGLE case CDDP-A8B5, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 65 years.
Specimen CDDP-A8B5-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 849fc17c-f2da-478b-af8c-449e8be03fe8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-A8B5-NB1-A (Blood Derived Normal), aliquot CDDP-A8B5-NB1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c320a7a-aad6-42e7-8417-300d8266cdc4

The open-access MAF lists 1,128 somatic variants for this specimen: 777 protein-altering or splice-affecting, 204 silent, 147 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 642, Silent 204, Nonsense Mutation 68, Intron 65, RNA 32, Frame Shift Del 29, 3'UTR 17, Splice Site 15, 5'UTR 14, 5'Flank 12, Splice Region 8, Frame Shift Ins 7.

Variants (750 of 1,128; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 332/428 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2313G>T p.R771S | Missense Mutation (SNP) | VAF 50/383 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV52226795; called by muse, varscan2
- ABCA13 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 246/379 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.44); catalogued as COSV70038132; called by muse, mutect2, varscan2
- ABCA13 | c.2297A>T p.D766V | Missense Mutation (SNP) | VAF 819/1206 reads (68%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV70038170; called by muse, mutect2, varscan2
- ABCA6 | c.4737G>C p.Q1579H | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV52642050; called by muse, varscan2
- ABCA9 | c.3766G>T p.G1256* | Nonsense Mutation (SNP) | VAF 75/256 reads (29%) | catalogued as COSV60626465, COSV60628612; called by muse, mutect2, varscan2
- ABCB7 | c.1133A>G p.N378S (on ENST00000373394 / NM_001271696.3; = p.N379S on NM_004299.6) | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53722043; called by muse, mutect2, varscan2
- ABCC8 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56854608; called by muse, mutect2, varscan2
- ABLIM2 | c.1516C>T p.R506* (on ENST00000341937 / NM_001130084.2; = p.Q455* on NM_032432.5) | Nonsense Mutation (SNP) | VAF 10/144 reads (7%) | catalogued as COSV56408599; called by muse, mutect2
- ABLIM2 | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56408621; called by muse, mutect2, varscan2
- ABLIM2 | c.305A>T p.Y102F | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV56408647; called by muse, mutect2, varscan2
- ABLIM3 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 99/143 reads (69%) | catalogued as COSV58646541; called by muse, mutect2, varscan2
- AC006059.2 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 78/170 reads (46%) | catalogued as COSV59608412, COSV59608469; called by muse, mutect2, varscan2
- AC011448.1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.87); catalogued as rs1267598168, COSV52278018; called by muse, mutect2, varscan2
- ACADM | c.928G>T p.G310* | Nonsense Mutation (SNP) | VAF 148/471 reads (31%) | catalogued as CM012322, COSV63720831; called by muse, mutect2, varscan2
- ACAN | c.6695C>G p.T2232R | Missense Mutation (SNP) | VAF 272/872 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV61365485; called by muse, mutect2, varscan2
- ACSS3 | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV54097020; called by muse, mutect2, varscan2
- ADAMTS12 | c.3770C>A p.P1257Q | Missense Mutation (SNP) | VAF 307/662 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); catalogued as COSV61271512; called by muse, mutect2, varscan2
- ADAMTS20 | c.5485G>A p.A1829T | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.209); catalogued as rs746458193, COSV101240628, COSV67135847; called by muse, mutect2, varscan2
- ADAMTS20 | c.2586G>T p.M862I | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.175); catalogued as rs373623926, COSV67135853; called by muse, mutect2, varscan2
- ADCY9 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV53574460; called by muse, mutect2, varscan2
- ADIPOR1 | c.141A>C p.K47N | Missense Mutation (SNP) | VAF 37/251 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61852106; called by muse, mutect2, varscan2
- AHNAK | c.6719A>C p.H2240P | Missense Mutation (SNP) | VAF 90/544 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV57223012; called by muse, mutect2, varscan2
- AHNAK2 | c.5429C>T p.S1810F | Missense Mutation (SNP) | VAF 93/1338 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1206221388; called by muse, mutect2
- AK8 | c.920T>C p.V307A | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.199); catalogued as COSV53757971; called by muse, mutect2, varscan2
- ALDH1A2 | c.1337T>C p.V446A | Missense Mutation (SNP) | VAF 230/375 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV51086821; called by muse, mutect2, varscan2
- ALDOB | c.113-1G>A p.X38_splice | Splice Site (SNP) | VAF 46/294 reads (16%) | catalogued as rs748663340, CS052027; called by muse, mutect2, varscan2
- ALKBH3 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV57025459; called by muse, mutect2, varscan2
- AMER2 | c.1687del p.D563Tfs*22 | Frame Shift Del (DEL) | VAF 41/190 reads (22%) | catalogued as COSV63436148; called by mutect2, pindel, varscan2
- ANK2 | c.4468C>A p.H1490N | Missense Mutation (SNP) | VAF 86/243 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.488); catalogued as COSV52159888; called by muse, mutect2, varscan2
- ANKRD26 | c.5071G>T p.D1691Y | Missense Mutation (SNP) | VAF 105/337 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs770823530, COSV101063470, COSV65776956; called by muse, mutect2, varscan2
- ANO5 | c.583C>G p.R195G | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV61088148, COSV61090944; called by muse, mutect2, varscan2
- ANP32A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 97/267 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV51189780; called by muse, mutect2, varscan2
- AOAH | c.1664T>A p.L555Q | Missense Mutation (SNP) | VAF 90/665 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV51746810; called by muse, mutect2, varscan2
- AP4E1 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 140/232 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV55918744; called by muse, mutect2, varscan2
- AP5S1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 240/479 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV55694439, COSV99853319; called by muse, mutect2, varscan2
- AP5Z1 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62242806; called by muse, mutect2
- APBB1 | c.722-1G>T p.X241_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as rs1352539038; called by muse, mutect2
- APPL1 | c.671A>T p.E224V | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV55702403; called by muse, mutect2, varscan2
- AQR | c.2790A>T p.E930D | Missense Mutation (SNP) | VAF 68/104 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50043045; called by muse, mutect2, varscan2
- ARAP2 | c.2293G>T p.D765Y | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV58289807; called by muse, varscan2
- ARFGEF1 | c.713A>T p.H238L | Missense Mutation (SNP) | VAF 76/962 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV51613675; called by muse, mutect2
- ARHGAP32 | c.659C>G p.S220* | Nonsense Mutation (SNP) | VAF 104/213 reads (49%) | catalogued as COSV59852683; called by muse, mutect2, varscan2
- ARHGAP33 | c.2026A>T p.I676L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV50138666; called by muse, mutect2, varscan2
- ARHGEF4 | c.1299G>C p.Q433H | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58122893, COSV58126476; called by muse, mutect2, varscan2
- ARRDC4 | c.613G>C p.G205R | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51419820; called by muse, mutect2, varscan2
- ARSH | c.95C>A p.T32K | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66963570; called by muse, mutect2, varscan2
- ASCL3 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV57941693; called by muse, mutect2, varscan2
- ASRGL1 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57125702; called by muse, mutect2, varscan2
- ASXL3 | c.2588T>G p.V863G | Missense Mutation (SNP) | VAF 180/400 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV52473338, COSV52473627; called by muse, varscan2
- ATP10D | c.3775A>G p.I1259V | Missense Mutation (SNP) | VAF 94/206 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV56710613; called by muse, mutect2, varscan2
- ATP2B2 | c.685A>T p.I229F | Missense Mutation (SNP) | VAF 205/426 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV59487916; called by muse, mutect2, varscan2
- ATP8A2 | c.1663-1G>T p.X555_splice | Splice Site (SNP) | VAF 31/198 reads (16%) | catalogued as COSV54975790, COSV99684804; called by muse, mutect2, varscan2
- AUTS2 | c.2858G>T p.R953M | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV61420139; called by muse, mutect2, varscan2
- AXL | c.1491G>C p.R497S (on ENST00000301178 / NM_021913.5; = p.R488S on NM_001699.6) | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.982); catalogued as COSV56572057; called by muse, mutect2, varscan2
- BACH2 | c.1402G>T p.V468L | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV57601712; called by muse, mutect2, varscan2
- BCHE | c.1726C>A p.H576N | Missense Mutation (SNP) | VAF 43/369 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV52259860; called by muse, mutect2, varscan2
- BCHE | c.1725C>A p.F575L | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV52259869; called by muse, mutect2, varscan2
- BCL11B | c.2300G>A p.R767H (on ENST00000357195 / NM_001282237.2; = p.R696H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs572644406; called by muse, mutect2
- BCO2 | c.836A>T p.K279I | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV63064284; called by muse, mutect2, varscan2
- BMP7 | c.6C>A p.H2Q | Missense Mutation (SNP) | VAF 251/428 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67781797; called by muse, mutect2, varscan2
- BRD1 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV53459889; called by muse, mutect2, varscan2
- BRINP3 | c.62T>A p.I21K | Missense Mutation (SNP) | VAF 121/609 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV66533416; called by muse, mutect2, varscan2
- BSND | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64870988; called by muse, mutect2, varscan2
- BTBD9 | c.787A>G p.M263V | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.087); catalogued as COSV58432009; called by muse, mutect2, varscan2
- C12orf50 | c.1171C>T p.R391* | Nonsense Mutation (SNP) | VAF 13/160 reads (8%) | catalogued as rs1007544930, COSV53897410; called by muse, mutect2
- C2orf78 | c.1763A>T p.K588M | Missense Mutation (SNP) | VAF 79/387 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV68518582; called by muse, mutect2, varscan2
- C6 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 149/702 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs544678725, COSV54708806; called by muse, mutect2, varscan2
- CA2 | c.422C>A p.A141D | Missense Mutation (SNP) | VAF 540/1187 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53407703, COSV99570393; called by muse, mutect2, varscan2
- CACNA1E | c.3731G>A p.G1244E | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62408034; called by muse, mutect2
- CACNA2D1 | c.2899G>A p.A967T (on ENST00000356253 / NM_001366867.1; = p.A955T on NM_000722.4) | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV62386726; called by muse, mutect2, varscan2
- CACNG7 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 160/300 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.747); catalogued as COSV55816145; called by muse, mutect2, varscan2
- CACNG8 | c.45C>A p.C15* | Nonsense Mutation (SNP) | VAF 32/115 reads (28%) | catalogued as COSV54415990; called by muse, mutect2, varscan2
- CACTIN | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 141/787 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs763973263, COSV50270790; called by muse, mutect2, varscan2
- CADM3 | c.1163C>T p.S388L (on ENST00000368125 / NM_001127173.3; = p.S422L on NM_021189.5) | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as COSV63673852; called by muse, mutect2, varscan2
- CADPS | c.55A>T p.S19C | Missense Mutation (SNP) | VAF 80/449 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.237); catalogued as COSV51892828; called by muse, mutect2, varscan2
- CAMSAP3 | c.2284C>T p.R762* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as rs757085387, COSV50344607; called by muse, mutect2, varscan2
- CAPRIN2 | c.1323G>C p.Q441H | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV51834170; called by muse, mutect2
- CASP3 | c.278G>C p.R93P | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as COSV57724950, COSV57725479; called by muse, mutect2, varscan2
- CASR | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 117/535 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV56139631; called by muse, mutect2, varscan2
- CASR | c.2255A>G p.Y752C (on ENST00000490131; = p.Y829C on NM_000388.4) | Missense Mutation (SNP) | VAF 126/1153 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as CM155248, COSV56139642; called by muse, mutect2, varscan2
- CASR | c.2489G>T p.G830V (on ENST00000490131; = p.G907V on NM_000388.4) | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.436); catalogued as COSV56134341, COSV56139655; called by muse, mutect2, varscan2
- CBLL2 | c.1076A>C p.H359P | Missense Mutation (SNP) | VAF 92/126 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV60369728; called by muse, mutect2, varscan2
- CBX2 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 47/478 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53969754; called by muse, mutect2
- CBX5 | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV52937937; called by muse, mutect2, varscan2
- CBY2 | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV60119192; called by muse, mutect2, varscan2
- CCDC15 | c.1087G>T p.V363F | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.525); catalogued as COSV61083548; called by muse, varscan2
- CCDC151 | c.111C>A p.S37R | Missense Mutation (SNP) | VAF 189/366 reads (52%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV52950273; called by muse, mutect2, varscan2
- CCDC168 | c.3244A>T p.S1082C | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV70555694; called by muse, mutect2, varscan2
- CCDC168 | c.1571A>G p.N524S | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as COSV70555696; called by muse, mutect2, varscan2
- CCDC175 | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV55791989; called by muse, mutect2, varscan2
- CCDC185 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752161726, COSV64821443; called by muse, mutect2, varscan2
- CCDC39 | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV56489501; called by muse, mutect2, varscan2
- CCDC73 | c.1212C>A p.N404K | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV58802005; called by muse, mutect2, varscan2
- CCDC8 | c.1190C>A p.A397D | Missense Mutation (SNP) | VAF 257/1225 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV56774167; called by muse, mutect2, varscan2
- CCER1 | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs1555214002, COSV62645852; called by muse, mutect2, varscan2
- CCNA2 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 169/513 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52658330, COSV99145025; called by muse, mutect2, varscan2
- CD14 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 143/198 reads (72%) | catalogued as COSV57371114; called by muse, mutect2, varscan2
- CD200 | c.594G>C p.K198N (on ENST00000473539 / NM_001004196.3; = p.K173N on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 140/664 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.054); catalogued as COSV59864021; called by muse, mutect2, varscan2
- CD28 | c.274A>C p.N92H | Missense Mutation (SNP) | VAF 136/388 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV60731241; called by muse, mutect2, varscan2
- CD300C | c.472C>A p.H158N | Missense Mutation (SNP) | VAF 43/291 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.209); catalogued as COSV100423136; called by muse, mutect2, varscan2
- CDH20 | c.1640A>C p.D547A | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53014329; called by muse, mutect2, varscan2
- CDH9 | c.2053G>T p.D685Y | Missense Mutation (SNP) | VAF 221/678 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV50273979, COSV99157206; called by muse, mutect2, varscan2
- CDHR1 | c.1235C>G p.T412R | Missense Mutation (SNP) | VAF 483/601 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1236899952, COSV60564384, COSV60564741; called by muse, mutect2, varscan2
- CDHR1 | c.1535A>G p.Y512C | Missense Mutation (SNP) | VAF 169/216 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200497503, COSV60564755; called by muse, mutect2, varscan2
- CDHR2 | c.2304C>A p.Y768* | Nonsense Mutation (SNP) | VAF 42/60 reads (70%) | catalogued as COSV56142447, COSV99991052; called by muse, mutect2
- CENPE | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs777841784, COSV54385620; called by muse, mutect2, varscan2
- CENPF | c.564G>T p.L188F | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs1219964224, COSV65277196; called by muse, mutect2, varscan2
- CEP126 | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV54828505; called by muse, mutect2, varscan2
- CEP170 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 29/313 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV63733193; called by muse, mutect2
- CEP85L | c.1797G>A p.M599I | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs867078042, COSV63825933; called by muse, mutect2, varscan2
- CES5A | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV72953978; called by muse, mutect2, varscan2
- CFAP20DC | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1231462961; called by muse, mutect2, varscan2
- CFAP57 | c.213C>A p.Y71* | Nonsense Mutation (SNP) | VAF 117/287 reads (41%) | catalogued as rs1557728456, COSV65265106; called by muse, varscan2
- CFAP70 | c.1956G>T p.E652D | Missense Mutation (SNP) | VAF 85/192 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV60285424; called by muse, mutect2, varscan2
- CFH | c.986A>G p.D329G | Missense Mutation (SNP) | VAF 204/804 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV62778356; called by muse, mutect2, varscan2
- CHD1 | c.1650G>C p.Q550H | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV52342885; called by muse, mutect2, varscan2
- CHI3L2 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.079); catalogued as COSV63874508; called by muse, mutect2, varscan2
- CHRNA1 | c.671A>T p.K224M (on ENST00000261007 / NM_001039523.3; = p.K199M on NM_000079.4) | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.771); catalogued as COSV53684186; called by muse, mutect2, varscan2
- CHST13 | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV60042858; called by muse, mutect2, varscan2
- CHST2 | c.1243T>A p.W415R | Missense Mutation (SNP) | VAF 112/177 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV58886410; called by muse, mutect2, varscan2
- CIDEA | c.528C>A p.F176L | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57600168; called by muse, mutect2
- CLEC3A | c.104G>T p.R35I (on ENST00000651443; = p.R26I on NM_005752.6) | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV55219887; called by muse, mutect2, varscan2
- CLINT1 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV51627049; called by muse, mutect2, varscan2
- CNTLN | c.3706G>T p.E1236* | Nonsense Mutation (SNP) | VAF 38/211 reads (18%) | catalogued as COSV52073990, COSV52088849; called by muse, varscan2
- CNTNAP5 | c.3448G>T p.D1150Y | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs374942023, COSV70506061; called by muse, mutect2, varscan2
- COBL | c.3200_3201del p.E1067Gfs*12 | Frame Shift Del (DEL) | VAF 102/297 reads (34%) | catalogued as rs1233484308; called by pindel, varscan2
- COL24A1 | c.3268C>A p.P1090T | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as rs1558458385, COSV65310273; called by muse, mutect2, varscan2
- COL25A1 | c.1096del p.E366Kfs*64 | Frame Shift Del (DEL) | VAF 55/277 reads (20%) | catalogued as COSV67651454; called by mutect2, pindel, varscan2
- COL27A1 | c.2674G>T p.G892C | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61929018; called by muse, mutect2, varscan2
- COL4A5 | c.4503A>T p.Q1501H | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60367108; called by muse, mutect2, varscan2
- COL5A1 | c.3023C>T p.T1008M | Missense Mutation (SNP) | VAF 63/450 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs199735010, COSV65667915; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 121/333 reads (36%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.982); catalogued as COSV66412278; called by muse, mutect2, varscan2
- COP1 | c.1033A>G p.K345E | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as COSV58172429; called by muse, mutect2
- COQ4 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as rs1049933076, COSV55957676; called by muse, mutect2, varscan2
- CPNE4 | c.753G>T p.E251D | Missense Mutation (SNP) | VAF 182/302 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV70196408; called by muse, mutect2, varscan2
- CPQ | c.664T>A p.Y222N | Missense Mutation (SNP) | VAF 150/477 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55154202; called by muse, mutect2, varscan2
- CPT1C | c.1847T>A p.M616K | Missense Mutation (SNP) | VAF 67/112 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54921016; called by muse, mutect2, varscan2
- CPXCR1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV52163598; called by muse, mutect2, varscan2
- CPZ | c.1468C>A p.H490N (on ENST00000360986 / NM_001014447.3; = p.H479N on NM_003652.3) | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV59924452; called by muse, mutect2, varscan2
- CR1 | c.5014G>T p.G1672W | Missense Mutation (SNP) | VAF 143/542 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65460918; called by muse, mutect2, varscan2
- CREBBP | c.7228C>T p.P2410S | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.994); catalogued as COSV52133890; called by muse, mutect2, varscan2
- CREBZF | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 95/187 reads (51%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.979); catalogued as COSV52630294; called by muse, mutect2, varscan2
- CRYBG2 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 60/490 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs745508045, COSV57487968; called by muse, mutect2, varscan2
- CRYZL1 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 69/384 reads (18%) | catalogued as COSV51678688; called by muse, mutect2, varscan2
- CSF3R | c.1404dup p.S469Qfs*5 | Frame Shift Ins (INS) | VAF 84/254 reads (33%) | catalogued as rs747437399; called by mutect2, varscan2
- CSMD1 | c.4940C>A p.T1647K (on ENST00000520002; = p.T1646K on NM_033225.6) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs758333832, COSV59319174; called by muse, varscan2
- CSMD3 | c.10119T>A p.S3373R (on ENST00000297405 / NM_001363185.1; = p.S3204R on NM_052900.3) | Missense Mutation (SNP) | VAF 370/602 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV52257175; called by muse, varscan2
- CSMD3 | c.9172G>T p.D3058Y (on ENST00000297405 / NM_001363185.1; = p.D2889Y on NM_052900.3) | Missense Mutation (SNP) | VAF 340/1302 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52105606, COSV52257196; called by muse, mutect2, varscan2
- CSMD3 | c.7494G>T p.M2498I (on ENST00000297405 / NM_001363185.1; = p.M2394I on NM_052900.3) | Missense Mutation (SNP) | VAF 66/786 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV52173201; called by muse, mutect2
- CSMD3 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 136/519 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV52257241; called by muse, mutect2, varscan2
- CTNNA2 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV58166928; called by muse, mutect2, varscan2
- CTNND2 | c.506C>A p.P169Q | Missense Mutation (SNP) | VAF 68/440 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV100476970, COSV58909274; called by muse, mutect2, varscan2
- CTSV | c.59A>T p.K20I | Missense Mutation (SNP) | VAF 82/164 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV52345362; called by muse, mutect2, varscan2
- CUL2 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as COSV66080086; called by muse, varscan2
- CXXC4 | c.507C>A p.S169R | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as COSV67296650; called by muse, varscan2
- CYB5RL | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 55/373 reads (15%) | catalogued as rs756215847, COSV55278187; called by muse, mutect2, varscan2
- CYLC1 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 69/96 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV61414212; called by muse, mutect2, varscan2
- CYP2B6 | c.1102C>A p.P368T | Missense Mutation (SNP) | VAF 145/533 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57844988; called by muse, mutect2, varscan2
- DAB2 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 26/961 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1435618871, COSV57913655; called by muse, mutect2
- DEFB113 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV59038313; called by muse, mutect2, varscan2
- DENND5B | c.47C>A p.P16Q | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV62809168; called by muse, mutect2, varscan2
- DGKG | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 47/271 reads (17%) | catalogued as rs1258341094, COSV53969318; called by muse, mutect2, varscan2
- DGKK | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 86/110 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); catalogued as rs782004080; called by muse, mutect2, varscan2
- DHX33 | c.239G>T p.R80L | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1439723960, COSV50147647; called by muse, varscan2
- DHX58 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52427225; called by muse, mutect2, varscan2
- DIP2C | c.1404G>T p.W468C | Missense Mutation (SNP) | VAF 139/410 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55170150; called by muse, mutect2, varscan2
- DISP1 | c.4503G>T p.M1501I | Missense Mutation (SNP) | VAF 129/671 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52662511; called by muse, mutect2, varscan2
- DLGAP1 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 133/328 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV59821953; called by muse, mutect2, varscan2
- DLGAP3 | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs764135834, COSV52393369; called by muse, mutect2
- DLGAP3 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1412135893, COSV52396015; called by muse, mutect2, varscan2
- DLK1 | c.1009C>A p.L337M | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV57992689; called by muse, mutect2, varscan2
- DMD | c.5275G>T p.E1759* | Nonsense Mutation (SNP) | VAF 141/225 reads (63%) | catalogued as COSV63776720; called by muse, mutect2, varscan2
- DNAH5 | c.4755G>T p.M1585I | Missense Mutation (SNP) | VAF 126/364 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV54241201; called by muse, mutect2, varscan2
- DNAH9 | c.6199G>T p.D2067Y | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs777605036, COSV52364296; called by muse, mutect2, varscan2
- DOCK10 | c.2231A>G p.D744G | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51422124; called by muse, mutect2, varscan2
- DOCK9 | c.5015G>T p.S1672I (on ENST00000376460 / NM_001366676.2; = p.S1673I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV59620016; called by muse, mutect2, varscan2
- DRD1 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 117/145 reads (81%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV67105001; called by muse, mutect2, varscan2
- DSE | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 98/159 reads (62%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV59066305; called by muse, mutect2, varscan2
- DSG1 | c.2330C>A p.P777Q | Missense Mutation (SNP) | VAF 142/594 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as COSV57137768; called by muse, mutect2, varscan2
- DTX3 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 94/315 reads (30%) | catalogued as COSV54089137; called by muse, mutect2, varscan2
- DYNC2H1 | c.6440A>G p.D2147G | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV62100957; called by muse, mutect2
- DYNC2H1 | c.11561A>G p.K3854R | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV62100963; called by muse, varscan2
- EFHB | c.2240G>T p.G747V | Missense Mutation (SNP) | VAF 112/339 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV55551111; called by muse, mutect2, varscan2
- EHD2 | c.1561G>T p.G521W | Missense Mutation (SNP) | VAF 61/399 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as COSV54409925; called by muse, mutect2, varscan2
- EIF2AK3 | c.1867A>G p.R623G | Missense Mutation (SNP) | VAF 122/534 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV57545850; called by muse, mutect2, varscan2
- ELMOD1 | c.189T>A p.S63R | Missense Mutation (SNP) | VAF 99/192 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56194521; called by muse, mutect2, varscan2
- ENY2 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV60565889; called by muse, mutect2
- EOMES | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767871834, COSV55413919; called by muse, mutect2, varscan2
- EPC1 | c.724A>C p.S242R | Missense Mutation (SNP) | VAF 89/457 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV53928174; called by muse, mutect2, varscan2
- EPHB1 | c.1379C>A p.P460H | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67666770; called by muse, mutect2, varscan2
- ESR1 | c.522G>T p.M174I | Missense Mutation (SNP) | VAF 214/316 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV52797443; called by muse, mutect2, varscan2
- EVI2B | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 165/422 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV58364668; called by muse, varscan2
- EYA4 | c.523C>G p.P175A | Missense Mutation (SNP) | VAF 280/454 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62057618; called by muse, mutect2, varscan2
- F11 | c.848G>T p.C283F | Missense Mutation (SNP) | VAF 102/420 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53008448; called by muse, mutect2, varscan2
- F2 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61316755; called by muse, mutect2, varscan2
- F5 | c.4054C>T p.L1352F | Missense Mutation (SNP) | VAF 237/997 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV63126235; called by muse, mutect2, varscan2
- F7 | c.1048C>A p.R350S | Missense Mutation (SNP) | VAF 117/392 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as CD920860, CM090309, COSV60645173, COSV60647180; called by muse, mutect2, varscan2
- FAM167A | c.121A>C p.T41P | Missense Mutation (SNP) | VAF 127/186 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52704729; called by mutect2, varscan2
- FAM200A | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1390134645, COSV68808906; called by muse, mutect2, varscan2
- FAM47A | c.99C>A p.C33* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV60498649; called by muse, mutect2, varscan2
- FAM91A1 | c.1334T>C p.L445P | Missense Mutation (SNP) | VAF 153/865 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232302646, COSV58238418; called by muse, mutect2, varscan2
- FAP | c.684T>A p.D228E | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51865061; called by muse, mutect2, varscan2
- FAR1 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61385771; called by muse, mutect2, varscan2
- FASLG | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 280/1082 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60680578; called by mutect2, varscan2
- FASTKD2 | c.942G>T p.M314I | Missense Mutation (SNP) | VAF 106/314 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as COSV52699377; called by muse, varscan2
- FASTKD5 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 60/1005 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as COSV53907840; called by muse, mutect2
- FBXL19 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1016785582, COSV57944347; called by muse, mutect2, varscan2
- FCER1A | c.554A>C p.Y185S | Missense Mutation (SNP) | VAF 44/426 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.367); catalogued as COSV63667909; called by muse, mutect2, varscan2
- FCHSD1 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as COSV71301561; called by muse, mutect2, varscan2
- FCRL2 | c.895C>A p.R299S | Missense Mutation (SNP) | VAF 62/807 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs369279577, COSV63834421; called by muse, mutect2
- FCRL5 | c.2266C>A p.L756I | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV62517710; called by muse, mutect2, varscan2
- FERD3L | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 34/536 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as COSV51763682, COSV51764415; called by muse, mutect2
- FEZF2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51863895; called by muse, mutect2
- FLNC | c.2383G>T p.G795W | Missense Mutation (SNP) | VAF 109/211 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57960742; called by muse, mutect2, varscan2
- FLNC | c.3778G>T p.V1260F | Missense Mutation (SNP) | VAF 174/417 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57960753; called by muse, mutect2, varscan2
- FLT3 | c.2579T>C p.L860P | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774360726, COSV54062492; called by muse, mutect2, varscan2
- FLYWCH2 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 74/374 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53559436; called by muse, mutect2, varscan2
- FMN2 | c.959C>A p.S320Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV60442945; called by muse, mutect2, varscan2
- FMN2 | c.4867G>C p.D1623H | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60442966; called by muse, mutect2
- FOCAD | c.2950G>T p.G984W | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV58104510, COSV58110434; called by muse, mutect2, varscan2
- FOXG1 | c.856T>C p.F286L | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV57398330; called by muse, mutect2
- FOXL1 | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 164/473 reads (35%) | catalogued as rs772398110, COSV57214868; called by muse, mutect2, varscan2
- FOXN1 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56881281; called by muse, mutect2, varscan2
- FOXS1 | c.296A>G p.H99R | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV54067502; called by muse, varscan2
- FSD2 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 144/539 reads (27%) | catalogued as COSV58011667; called by muse, mutect2, varscan2
- FSIP2 | c.4639G>T p.E1547* | Nonsense Mutation (SNP) | VAF 81/227 reads (36%) | catalogued as COSV58093743; called by muse, mutect2, varscan2
- GABRG3 | c.1298G>T p.R433L | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs763239710, COSV61512410, COSV61526050; called by muse, mutect2, varscan2
- GABRR1 | c.1258C>A p.P420T | Missense Mutation (SNP) | VAF 247/399 reads (62%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV65619162; called by muse, mutect2, varscan2
- GAD2 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 64/364 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52163477; called by muse, mutect2, varscan2
- GAL3ST2 | c.713G>C p.R238P | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51951037; called by muse, mutect2, varscan2
- GALC | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 108/635 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); catalogued as rs1373938575, COSV54328179; called by muse, mutect2, varscan2
- GALR1 | c.542C>A p.A181D | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.075); catalogued as COSV55318315; called by muse, mutect2, varscan2
- GALR3 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV50764253; called by muse, mutect2, varscan2
- GATA4 | c.1286G>A p.S429N | Missense Mutation (SNP) | VAF 41/372 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as CM086818; called by mutect2, varscan2
- GIMAP4 | c.980C>A p.A327E | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV55433821; called by muse, mutect2, varscan2
- GLI2 | c.3781G>T p.G1261W (on ENST00000361492 / NM_001374353.1; = p.G1278W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV58047284; called by muse, mutect2, varscan2
- GLRB | c.813G>T p.M271I | Missense Mutation (SNP) | VAF 168/537 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.48); catalogued as COSV52417708, COSV52420097; called by muse, mutect2, varscan2
- GOLGA8S | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 107/1069 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as rs759061426, COSV101494933; called by muse, mutect2, varscan2
- GOLIM4 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 55/218 reads (25%) | catalogued as COSV58329007, COSV58330989; called by muse, mutect2, varscan2
- GPR158 | c.1105T>G p.F369V | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); catalogued as COSV66268941; called by muse, mutect2, varscan2
- GPR174 | c.371T>A p.F124Y | Missense Mutation (SNP) | VAF 200/260 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52133543; called by muse, mutect2, varscan2
- GPR31 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 100/137 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64761804; called by muse, mutect2, varscan2
- GPR31 | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 115/209 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV64761808; called by muse, mutect2, varscan2
- GPR31 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 113/209 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV64761816; called by muse, mutect2, varscan2
- GPRASP1 | c.1784G>T p.R595M | Missense Mutation (SNP) | VAF 147/185 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV64356149; called by muse, mutect2, varscan2
- GPSM1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as rs1554770107, COSV61305041; called by muse, mutect2, varscan2
- GRHL3 | c.1054A>T p.I352F (on ENST00000350501 / NM_198174.3; = p.I357F on NM_021180.3) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV52569334; called by muse, mutect2, varscan2
- GRIK1 | c.100C>G p.P34A | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58726276; called by muse, mutect2, varscan2
- GRIN2B | c.74G>T p.R25I | Missense Mutation (SNP) | VAF 111/292 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV74206956; called by muse, mutect2, varscan2
- GRIN2D | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV54381015; called by muse, mutect2, varscan2
- GRIN3B | c.579C>A p.S193R | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV52262009; called by muse, mutect2, varscan2
- GRIP1 | c.938C>A p.T313K | Missense Mutation (SNP) | VAF 68/648 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV54034189; called by muse, mutect2, varscan2
- GRK3 | c.1292G>T p.R431L | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV60793575, COSV60798794; called by muse, mutect2, varscan2
- GRM5 | c.1056C>A p.N352K | Missense Mutation (SNP) | VAF 53/360 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59617455; called by muse, mutect2, varscan2
- GRM7 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 23/275 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1032302204, COSV63142847, COSV63157383; called by muse, mutect2
- GXYLT1 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 58/556 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1336926091, COSV55139954; called by muse, mutect2, varscan2
- HACE1 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 139/208 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV53505221; called by muse, mutect2, varscan2
- HAS1 | c.621C>A p.C207* | Nonsense Mutation (SNP) | VAF 67/106 reads (63%) | catalogued as COSV55788734, COSV55788872; called by muse, mutect2, varscan2
- HAUS5 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52549058; called by muse, mutect2, varscan2
- HEPH | c.3036+1G>A p.X1012_splice (on ENST00000343002; = p.X745_splice on NM_014799.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 25/40 reads (63%) | catalogued as rs1003289874; called by muse, mutect2, varscan2
- HGF | c.1361C>A p.T454K | Missense Mutation (SNP) | VAF 224/488 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55945201, COSV55953678; called by muse, mutect2, varscan2
- HIPK3 | c.3554C>G p.P1185R | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV57564342; called by muse, mutect2, varscan2
- HLX | c.1352G>T p.C451F | Missense Mutation (SNP) | VAF 138/296 reads (47%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs576515869, COSV65045336; called by muse, mutect2, varscan2
- HNRNPA1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV52937943; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 443/716 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as COSV61160406; called by muse, mutect2, varscan2
- HPS5 | c.1480G>A p.D494N (on ENST00000349215 / NM_181507.2; = p.D380N on NM_007216.4) | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV61687778; called by muse, mutect2, varscan2
- HS3ST2 | c.108C>A p.S36R | Missense Mutation (SNP) | VAF 235/456 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV54465816; called by muse, mutect2, varscan2
- HS3ST2 | c.511A>G p.S171G | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54465842; called by muse, mutect2, varscan2
- HSD17B4 | c.2047G>C p.G683R (on ENST00000414835 / NM_001199291.3; = p.G658R on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 192/581 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as CM123281, COSV56337884; called by muse, mutect2, varscan2
- HSF2BP | c.219G>C p.Q73H | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV52358258; called by muse, mutect2, varscan2
- HTATSF1 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 116/154 reads (75%) | catalogued as COSV54480131, COSV54480338, COSV54481279; called by muse, mutect2, varscan2
- HUWE1 | c.5356A>T p.T1786S | Missense Mutation (SNP) | VAF 81/156 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53356752; called by muse, mutect2, varscan2
- IARS2 | c.2203G>T p.G735* | Nonsense Mutation (SNP) | VAF 105/320 reads (33%) | catalogued as COSV56962133; called by muse, mutect2, varscan2
- IDH3B | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 84/1222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66483757; called by muse, mutect2
- IGLV3-32 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 116/351 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1258358714; called by muse, mutect2, varscan2
- IGSF11 | c.985C>A p.H329N (on ENST00000393775 / NM_001015887.3; = p.H328N on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/696 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100677311, COSV61174390; called by muse, mutect2
- IL23R | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV61374579; called by muse, mutect2, varscan2
- IL7R | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 75/461 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV57411132, COSV57414092; called by muse, mutect2, varscan2
- ILDR2 | c.1444A>T p.S482C | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV54833667; called by muse, mutect2, varscan2
- ILKAP | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 94/251 reads (37%) | catalogued as COSV54519311; called by muse, mutect2, varscan2
- INHBA | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 23/563 reads (4%) | catalogued as COSV54221978, COSV54223528; called by muse, mutect2
- INSC | c.147G>T p.M49I | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); catalogued as COSV65412099; called by muse, varscan2
- IRGQ | c.1636C>T p.H546Y | Missense Mutation (SNP) | VAF 105/190 reads (55%) | SIFT tolerated (0.94); PolyPhen benign (0.087); catalogued as COSV60671133; called by muse, mutect2, varscan2
- IRS2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 60/465 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65479982; called by muse, mutect2, varscan2
- ISLR2 | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62301802, COSV62302852; called by muse, mutect2, varscan2
- ITIH2 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 156/207 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV64434344; called by muse, mutect2, varscan2
- IVL | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 30/345 reads (9%) | catalogued as rs865873034, COSV64216747; called by muse, mutect2
- JAG2 | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as rs758419917, COSV59311280; called by muse, mutect2
- KAT2B | c.1969A>C p.T657P | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332566768, COSV55432389; called by muse, mutect2, varscan2
- KCNA1 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1053557642, COSV66836572; called by muse, mutect2, varscan2
- KCNA7 | c.245C>A p.A82E | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as COSV55504041; called by muse, mutect2, varscan2
- KCNT1 | c.1660C>A p.R554S (on ENST00000488444; = p.R573S on NM_020822.3) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as COSV53706654; called by muse, mutect2, varscan2
- KCNU1 | c.2142C>A p.N714K | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV67758334; called by muse, mutect2, varscan2
- KCNV1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52084789; called by muse, mutect2
- KCNV1 | c.512C>A p.T171K | Missense Mutation (SNP) | VAF 169/276 reads (61%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV52087701; called by muse, mutect2, varscan2
- KIAA0895 | c.459A>T p.K153N (on ENST00000297063 / NM_001100425.2; = p.K102N on NM_015314.3) | Missense Mutation (SNP) | VAF 419/622 reads (67%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV51712834; called by muse, mutect2, varscan2
- KIAA1217 | c.4772C>G p.T1591S | Missense Mutation (SNP) | VAF 353/709 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV56820317; called by muse, mutect2, varscan2
- KIAA2012 | c.974G>A p.C325Y | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1189711100, COSV55577051; called by muse, mutect2, varscan2
- KIF15 | c.1602A>T p.K534N | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV58163339; called by muse, mutect2, varscan2
- KIF2B | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 70/432 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1275459238, COSV52130460; called by muse, mutect2, varscan2
- KLF5 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 59/403 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV66615030, COSV66615930; called by muse, mutect2, varscan2
- KLHDC2 | c.70A>G p.M24V | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV53588009; called by muse, mutect2, varscan2
- KLHL22 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.113); catalogued as rs749157529, COSV61020249; called by muse, mutect2, varscan2
- KRR1 | c.1004-2A>G p.X335_splice | Splice Site (SNP) | VAF 98/376 reads (26%) | catalogued as rs772657477; called by muse, mutect2, varscan2
- KRT15 | c.1051G>T p.A351S | Missense Mutation (SNP) | VAF 106/299 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV54178952; called by muse, mutect2, varscan2
- KRT74 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 194/567 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59772749; called by muse, mutect2, varscan2
- KRT74 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 281/848 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV104399485, COSV59772759; called by muse, mutect2, varscan2
- KRT9 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 108/262 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV55854508; called by muse, mutect2, varscan2
- KRTAP13-1 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV62663927; called by muse, mutect2, varscan2
- KRTAP13-4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as COSV61879142; called by muse, mutect2, varscan2
- KRTAP19-3 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 97/621 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.604); catalogued as rs1349039050, COSV61854967; called by muse, mutect2, varscan2
- KRTAP27-1 | c.419G>T p.S140I | Missense Mutation (SNP) | VAF 158/291 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs1036987724, COSV67001466; called by muse, mutect2, varscan2
- KRTAP4-3 | c.466A>G p.I156V | Missense Mutation (SNP) | VAF 84/328 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV66940888; called by muse, varscan2
- KYNU | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.193); catalogued as rs749561053, COSV51588302; called by mutect2, varscan2
- L1TD1 | c.247G>T p.G83* | Nonsense Mutation (SNP) | VAF 73/225 reads (32%) | catalogued as COSV63133941; called by muse, mutect2, varscan2
- L1TD1 | c.2386T>A p.L796I | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63133946; called by muse, mutect2, varscan2
- LAMA2 | c.2611C>A p.L871I | Missense Mutation (SNP) | VAF 210/418 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV70352303; called by muse, mutect2, varscan2
- LAMA2 | c.4959G>C p.R1653S | Missense Mutation (SNP) | VAF 196/319 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs759672711, COSV70352304; called by muse, mutect2, varscan2
- LAMB4 | c.3091C>A p.P1031T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV52725778; called by muse, mutect2, varscan2
- LCE6A | c.65G>T p.R22I | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as COSV70391018, COSV70391230, COSV70391244; called by muse, mutect2
- LHX2 | c.195C>A p.Y65* | Nonsense Mutation (SNP) | VAF 187/338 reads (55%) | catalogued as COSV65318816; called by muse, mutect2, varscan2
- LINGO2 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as rs573296877, COSV58062063; called by muse, mutect2, varscan2
- LPAR2 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV52558465; called by muse, mutect2, varscan2
- LPO | c.1970A>T p.Q657L | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51861023; called by muse, mutect2, varscan2
- LRP1B | c.12092C>A p.A4031D | Missense Mutation (SNP) | VAF 89/277 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV67227292, COSV67252406; called by muse, mutect2, varscan2
- LRP1B | c.11024G>T p.R3675I | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV67252407; called by muse, mutect2, varscan2
- LRP1B | c.11008G>T p.G3670* | Nonsense Mutation (SNP) | VAF 19/134 reads (14%) | catalogued as COSV67252408; called by muse, mutect2, varscan2
- LRP2 | c.13091C>A p.T4364N | Missense Mutation (SNP) | VAF 167/537 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV55564846; called by muse, mutect2, varscan2
- LRRC37B | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV58953735; called by muse, mutect2, varscan2
- LRRC37B | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 110/265 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV58953743; called by muse, varscan2
- LRRC39 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.081); catalogued as COSV61583576; called by muse, mutect2, varscan2
- LRRC7 | c.4269C>A p.S1423R (on ENST00000651989 / NM_001370785.2; = p.S1343R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV50531903; called by muse, mutect2, varscan2
- LRRN3 | c.1880C>A p.T627K | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV57820751, COSV57822290; called by muse, mutect2, varscan2
- LY75 | c.2071G>A p.V691M | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55110203; called by muse, mutect2, varscan2
- MAD1L1 | c.1768G>T p.A590S | Missense Mutation (SNP) | VAF 100/574 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.031); catalogued as COSV56241905; called by muse, mutect2, varscan2
- MAGI2 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | catalogued as COSV62682875; called by muse, mutect2, varscan2
- MAGI2 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV62676186, COSV62682880; called by muse, mutect2, varscan2
- MAN1B1 | c.837G>T p.R279S | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV65378319; called by muse, mutect2, varscan2
- MAP1B | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57103191; called by muse, mutect2, varscan2
- MAP2 | c.5452G>A p.V1818I | Missense Mutation (SNP) | VAF 97/268 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52300673; called by muse, mutect2, varscan2
- MARK1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 74/324 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs748437550, COSV65069795; called by muse, mutect2, varscan2
- MATK | c.1303G>A p.E435K (on ENST00000310132 / NM_139355.3; = p.E436K on NM_002378.4) | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.887); catalogued as COSV59555889; called by muse, mutect2, varscan2
- MATK | c.1243T>A p.W415R (on ENST00000310132 / NM_139355.3; = p.W416R on NM_002378.4) | Missense Mutation (SNP) | VAF 232/512 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59555902; called by muse, mutect2, varscan2
- MCIDAS | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 129/290 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV72813325; called by muse, mutect2, varscan2
- MDGA2 | c.2758T>A p.L920I (on ENST00000399232 / NM_001113498.2; = p.L622I on NM_182830.4) | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100638894, COSV62105064; called by muse, mutect2
- MED12L | c.242T>G p.L81R | Missense Mutation (SNP) | VAF 111/183 reads (61%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.916); catalogued as COSV56388732; called by muse, mutect2, varscan2
- MGA | c.3946G>T p.G1316* | Nonsense Mutation (SNP) | VAF 70/103 reads (68%) | catalogued as COSV54959334; called by muse, varscan2
- MGAM | c.3065del p.K1022Sfs*14 | Frame Shift Del (DEL) | VAF 71/440 reads (16%) | catalogued as rs1407791060; called by pindel, varscan2
- MIA2 | c.1100C>A p.T367N | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as COSV54485193, COSV99696783; called by muse, varscan2
- MICAL2 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as COSV56323426; called by muse, mutect2, varscan2
- MID1 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58197660; called by muse, mutect2
- MMP26 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 51/437 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV56172144; called by muse, mutect2, varscan2
- MMRN1 | c.315A>T p.K105N | Missense Mutation (SNP) | VAF 75/469 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.157); catalogued as COSV53340566; called by muse, mutect2, varscan2
- MMRN1 | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 95/643 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.446); catalogued as COSV53340573; called by muse, mutect2, varscan2
- MORC1 | c.2459A>C p.K820T | Missense Mutation (SNP) | VAF 138/453 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.852); catalogued as COSV51726184; called by muse, mutect2, varscan2
- MORN1 | c.1127C>A p.P376Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66006490; called by muse, mutect2, varscan2
- MPDZ | c.6086G>C p.G2029A (on ENST00000319217 / NM_001330637.2; = p.G2000A on NM_003829.5) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59921376; called by muse, mutect2, varscan2
- MS4A12 | c.371C>A p.S124Y | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50015045; called by muse, mutect2, varscan2
- MT2A | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 66/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55330141; called by muse, mutect2, varscan2
- MTMR14 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 94/648 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs752231256, COSV56003691; called by muse, mutect2, varscan2
- MTR | c.2850A>T p.P950= | Splice Region (SNP) | VAF 160/581 reads (28%) | catalogued as COSV63964024, COSV63965846; called by muse, mutect2, varscan2
- MUC12 | c.2096C>T p.P699L (on ENST00000379442; = p.P556L on NM_001164462.1) | Missense Mutation (SNP) | VAF 200/441 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.722); catalogued as rs1395479444, COSV65201915; called by muse, mutect2, varscan2
- MUC16 | c.28706G>T p.G9569V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.737); catalogued as COSV67480828; called by muse, mutect2, varscan2
- MUC17 | c.7561C>T p.P2521S | Missense Mutation (SNP) | VAF 118/268 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.857); catalogued as rs768124622, COSV60297036; called by muse, mutect2, varscan2
- MUC2 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 144/245 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1341326883; called by muse, mutect2, varscan2
- MUC4 | c.157A>T p.T53S | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.301); catalogued as COSV62171146; called by muse, mutect2, varscan2
- MYH1 | c.348C>T p.Y116= | Splice Region (SNP) | VAF 103/138 reads (75%) | catalogued as rs768724975, COSV55430953; called by muse, mutect2, varscan2
- MYH13 | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 188/281 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773173964, COSV52836542; called by muse, mutect2, varscan2
- MYH15 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 105/326 reads (32%) | catalogued as COSV56315679; called by muse, mutect2, varscan2
- MYH6 | c.3913C>T p.R1305W | Missense Mutation (SNP) | VAF 61/600 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763328656, COSV62450708; called by muse, mutect2, varscan2
- MYLK2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV65659588; called by muse, varscan2
- MYLK3 | c.1442A>T p.E481V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV101189138, COSV67365665; called by muse, mutect2
- MYRIP | c.462C>A p.D154E | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.698); catalogued as COSV56876596; called by muse, mutect2, varscan2
- MZT2B | c.318A>T p.R106= | Splice Region (SNP) | VAF 41/184 reads (22%) | catalogued as COSV56059537; called by muse, mutect2, varscan2
- N4BP2L2 | c.2531G>T p.R844M (on ENST00000674422; = p.R415M on NM_033111.4) | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV62634241; called by muse, mutect2, varscan2
- NAA15 | c.1877A>C p.K626T | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.624); catalogued as COSV56721412; called by muse, mutect2, varscan2
- NAT8L | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 50/423 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV59052173; called by muse, mutect2, varscan2
- NAV3 | c.4552T>C p.C1518R | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57099177; called by muse, mutect2, varscan2
- NBEA | c.7915C>T p.P2639S | Missense Mutation (SNP) | VAF 86/363 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV59806000; called by muse, mutect2, varscan2
- NECAB3 | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 99/185 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV55777466; called by muse, mutect2, varscan2
- NEFL | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 492/700 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV55337824; called by muse, mutect2, varscan2
- NEFM | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 107/144 reads (74%) | catalogued as COSV55333864; called by muse, mutect2, varscan2
- NEK10 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 29/310 reads (9%) | catalogued as rs200480732; called by muse, mutect2
- NELL2 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61581008, COSV61582177; called by muse, mutect2, varscan2
- NET1 | c.916A>C p.S306R (on ENST00000355029 / NM_001047160.3; = p.S252R on NM_005863.5) | Missense Mutation (SNP) | VAF 159/385 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61792122; called by muse, mutect2, varscan2
- NEU3 | c.480C>G p.C160W | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53638100; called by muse, mutect2, varscan2
- NGEF | c.1203G>T p.R401S | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV50936621; called by muse, mutect2, varscan2
- NIBAN1 | c.2344G>T p.G782W | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV62286597; called by muse, mutect2, varscan2
- NLGN3 | c.2315A>G p.H772R (on ENST00000358741 / NM_181303.2; = p.H752R on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV62444554; called by muse, mutect2, varscan2
- NLGN4X | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 152/220 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52008771, COSV52025322; called by muse, mutect2, varscan2
- NLRC4 | c.2709G>C p.L903F | Missense Mutation (SNP) | VAF 74/422 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.781); catalogued as COSV61593940; called by muse, mutect2, varscan2
- NLRP1 | c.2959C>A p.R987= | Splice Region (SNP) | VAF 83/150 reads (55%) | catalogued as COSV52563658, COSV52572656; called by muse, mutect2, varscan2
- NLRP12 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 126/724 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV60751306; called by muse, mutect2, varscan2
- NOD2 | c.2603C>A p.A868E | Missense Mutation (SNP) | VAF 163/456 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV56053279; called by muse, mutect2, varscan2
- NOS1 | c.3283A>T p.I1095F | Missense Mutation (SNP) | VAF 62/424 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); catalogued as COSV57617592; called by muse, mutect2, varscan2
- NPAP1 | c.2738C>A p.S913Y | Missense Mutation (SNP) | VAF 95/154 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV61504085, COSV61507434, COSV61509490; called by muse, mutect2, varscan2
- NPC2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 95/726 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as CM096691, COSV53143980; called by muse, mutect2, varscan2
- NPNT | c.1479C>G p.H493Q | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV59755753; called by muse, mutect2, varscan2
- NR1D2 | c.1495A>C p.S499R | Missense Mutation (SNP) | VAF 130/478 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs768646319, COSV56993002; called by muse, mutect2, varscan2
- NRDE2 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 65/416 reads (16%) | catalogued as COSV62964096; called by muse, mutect2, varscan2
- NREP | c.52C>G p.R18G | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV67401638; called by muse, mutect2, varscan2
- NRXN1 | c.1263C>G p.S421R | Missense Mutation (SNP) | VAF 85/139 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58475566; called by muse, mutect2, varscan2
- NRXN1 | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV68018543, COSV68030373; called by muse, mutect2, varscan2
- NRXN3 | c.3218G>T p.C1073F (on ENST00000335750 / NM_001330195.2; = p.C700F on NM_004796.6) | Missense Mutation (SNP) | VAF 48/467 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59781165; called by muse, mutect2, varscan2
- NTRK2 | c.719T>C p.M240T | Missense Mutation (SNP) | VAF 79/508 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.18); catalogued as rs200807970, COSV52873671; called by muse, mutect2, varscan2
- NTRK3 | c.278C>A p.T93K | Missense Mutation (SNP) | VAF 283/642 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0.185); catalogued as CM1412106, COSV58125708, COSV58133636; called by muse, mutect2, varscan2
- NUBP1 | c.409A>T p.S137C | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51594801; called by muse, mutect2, varscan2
- NYAP2 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56011902; called by muse, mutect2, varscan2
- OBSCN | c.12213G>T p.K4071N | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as COSV52763121; called by muse, mutect2, varscan2
- OCA2 | c.2381C>G p.A794G | Missense Mutation (SNP) | VAF 65/326 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV62352688; called by muse, mutect2, varscan2
- OGDH | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 43/695 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs752306297, COSV56054256; called by muse, mutect2
- OGDHL | c.353A>T p.Q118L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.558); catalogued as COSV65103755; called by muse, mutect2
- OLFM1 | c.1172A>G p.Q391R (on ENST00000371793 / NM_001282611.2; = p.Q373R on NM_014279.5) | Missense Mutation (SNP) | VAF 45/315 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV53280793; called by muse, mutect2, varscan2
- OR13C2 | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 121/264 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV73377758; called by muse, varscan2
- OR13C4 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as rs1338056963, COSV52927783; called by muse, mutect2, varscan2
- OR14I1 | c.317C>A p.A106E | Missense Mutation (SNP) | VAF 54/637 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV61200389; called by muse, mutect2
- OR14I1 | c.189C>G p.N63K | Missense Mutation (SNP) | VAF 95/320 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61200395; called by muse, mutect2, varscan2
- OR2L8 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 43/332 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV61727644; called by muse, mutect2, varscan2
- OR2M4 | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV60709051; called by muse, mutect2, varscan2
- OR2M5 | c.160C>A p.Q54K | Missense Mutation (SNP) | VAF 57/587 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs1251873628; called by muse, mutect2, varscan2
- OR3A2 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 179/458 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68695202; called by muse, mutect2, varscan2
- OR4C16 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100114283, COSV100114301, COSV58941723; called by muse, mutect2, varscan2
- OR4K2 | c.86T>C p.M29T | Missense Mutation (SNP) | VAF 164/383 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1047892238, COSV53850789; called by muse, mutect2, varscan2
- OR4S2 | c.53G>T p.S18I | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1380360716, COSV56746505, COSV56747709; called by muse, mutect2, varscan2
- OR4X1 | c.804A>G p.I268M | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV60723435; called by muse, mutect2, varscan2
- OR5L1 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 101/247 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as rs770618559, COSV61734796; called by muse, mutect2, varscan2
- OR5P2 | c.470C>A p.T157N | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as rs1366709553, COSV61490972; called by muse, mutect2, varscan2
- OR5P3 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV60429622; called by muse, mutect2, varscan2
- OR5R1 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.633); catalogued as COSV56573114; called by muse, mutect2
- OR5T3 | c.690T>A p.C230* | Nonsense Mutation (SNP) | VAF 43/240 reads (18%) | catalogued as COSV57381853; called by muse, mutect2, varscan2
- OR6X1 | c.839C>A p.T280N | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV60010180; called by muse, mutect2, varscan2
- OR9K2 | c.388G>C p.A130P (on ENST00000305377; = p.A108P on NM_001005243.1) | Missense Mutation (SNP) | VAF 109/354 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV59532705; called by muse, mutect2, varscan2
- OR9Q2 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 137/252 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV61112404, COSV61112483; called by muse, mutect2, varscan2
- OSBPL11 | c.438G>T p.W146C | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56175441; called by muse, mutect2, varscan2
- OTOGL | c.3097A>C p.T1033P (on ENST00000547103; = p.T1024P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV72007068; called by muse, mutect2, varscan2
- PAOX | c.1397A>G p.Q466R | Missense Mutation (SNP) | VAF 195/456 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV53373357; called by muse, mutect2, varscan2
- PARD6G | c.113A>T p.K38M | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV62062143; called by muse, mutect2, varscan2
- PARG | c.2569G>T p.V857F | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV67859527; called by muse, mutect2, varscan2
- PARP8 | c.2112G>A p.W704* | Nonsense Mutation (SNP) | VAF 36/350 reads (10%) | catalogued as COSV55863732; called by muse, mutect2
- PC | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs757720464; called by muse, mutect2, varscan2
- PCDH10 | c.586G>C p.V196L | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV52099783; called by muse, mutect2, varscan2
- PCDH8 | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58814264; called by muse, mutect2, varscan2
- PCDHA7 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 90/887 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65341523; called by muse, mutect2, varscan2
- PCDHB14 | c.2323C>G p.Q775E | Missense Mutation (SNP) | VAF 124/331 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.028); catalogued as COSV53386310, COSV53389919; called by muse, mutect2, varscan2
- PCDHB5 | c.1615del p.A539Rfs*2 | Frame Shift Del (DEL) | VAF 267/1002 reads (27%) | catalogued as COSV50657271, COSV99167804; called by mutect2, pindel, varscan2
- PCDHGA9 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV53994676; called by muse, mutect2, varscan2
- PCDHGB7 | c.1666A>T p.N556Y | Missense Mutation (SNP) | VAF 186/245 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53994695; called by muse, mutect2, varscan2
- PCM1 | c.2257A>G p.R753G | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61518076; called by muse, mutect2, varscan2
- PCNA | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 75/157 reads (48%) | catalogued as COSV52532887; called by muse, varscan2
- PDE1B | c.915G>C p.Q305H | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as COSV54494752; called by muse, mutect2, varscan2
- PDE1C | c.1221G>T p.E407D | Missense Mutation (SNP) | VAF 41/369 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs555577593, COSV58521826; called by muse, mutect2, varscan2
- PDE4B | c.1174A>G p.M392V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1483225921, COSV58487582; called by muse, mutect2, varscan2
- PEAK1 | c.2853A>T p.K951N | Missense Mutation (SNP) | VAF 130/445 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV56940045; called by muse, mutect2, varscan2
- PEX3 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 67/298 reads (22%) | catalogued as COSV62569202; called by muse, mutect2, varscan2
- PGAP3 | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 64/269 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV56132141; called by muse, mutect2, varscan2
- PGR | c.135G>C p.L45F | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.093); catalogued as COSV54806802, COSV99679187; called by muse, mutect2, varscan2
- PHYHIPL | c.1030A>C p.T344P | Missense Mutation (SNP) | VAF 165/214 reads (77%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV53252749; called by muse, mutect2
- PIGZ | c.71G>T p.C24F | Missense Mutation (SNP) | VAF 156/602 reads (26%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV53014204; called by muse, mutect2, varscan2
- PKD1 | c.8716G>A p.G2906S | Missense Mutation (SNP) | VAF 101/818 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376611349, CM1111448; called by muse, mutect2, varscan2
- PKD1L1 | c.2813C>G p.A938G | Missense Mutation (SNP) | VAF 254/376 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56972492; called by muse, mutect2, varscan2
- PKHD1 | c.9360C>A p.D3120E | Missense Mutation (SNP) | VAF 258/511 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.176); catalogued as COSV61887725; called by muse, mutect2, varscan2
- PKHD1 | c.3452C>T p.P1151L | Missense Mutation (SNP) | VAF 46/379 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs574099162, COSV61872779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.1588G>T p.A530S | Missense Mutation (SNP) | VAF 85/580 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as COSV61887764; called by muse, mutect2, varscan2
- PKIA | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 29/477 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs11544889, COSV61915572; called by muse, mutect2
- PLCB1 | c.1418C>A p.S473* | Nonsense Mutation (SNP) | VAF 16/294 reads (5%) | catalogued as COSV62047241; called by muse, mutect2
- PLCB3 | c.1741A>T p.S581C | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV54190842; called by muse, mutect2, varscan2
- PLEKHS1 | c.869G>T p.G290V (on ENST00000369310 / NM_182601.1; = p.G296V on NM_024889.5) | Missense Mutation (SNP) | VAF 473/581 reads (81%) | SIFT tolerated (0.1); PolyPhen benign (0.421); catalogued as COSV63056218; called by muse, mutect2, varscan2
- PLXNA2 | c.4859G>T p.R1620I | Missense Mutation (SNP) | VAF 176/364 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV65443024; called by muse, mutect2
- PLXNA4 | c.3059C>A p.S1020* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | catalogued as COSV58146676; called by muse, mutect2, varscan2
- PMPCB | c.450G>T p.L150F | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV50787038; called by muse, mutect2, varscan2
- PNPT1 | c.679G>T p.V227F | Missense Mutation (SNP) | VAF 91/198 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53178904; called by muse, mutect2, varscan2
- POLR1F | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 314/512 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV55999178; called by muse, mutect2, varscan2
- POM121L12 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 100/702 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1358921097, COSV68693630; called by muse, mutect2, varscan2
- POM121L2 | c.2269G>T p.G757* | Nonsense Mutation (SNP) | VAF 61/414 reads (15%) | catalogued as COSV66276834; called by muse, mutect2, varscan2
- POM121L2 | c.2268G>T p.L756F | Missense Mutation (SNP) | VAF 60/413 reads (15%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.7); catalogued as COSV66276838; called by muse, mutect2, varscan2
- POU2F1 | c.360G>T p.Q120H (on ENST00000541643 / NM_001365848.1; = p.Q143H on NM_002697.4) | Missense Mutation (SNP) | VAF 184/709 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.969); catalogued as COSV54821559; called by muse, mutect2, varscan2
- POU3F3 | c.677G>C p.G226A | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.542); catalogued as COSV63722165; called by muse, mutect2, varscan2
- PPFIA2 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV61044693; called by muse, mutect2, varscan2
- PRAG1 | c.4014G>T p.Q1338H | Missense Mutation (SNP) | VAF 178/248 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV58164497; called by muse, mutect2, varscan2
- PRAG1 | c.3816G>T p.E1272D | Missense Mutation (SNP) | VAF 188/350 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV58164507; called by muse, mutect2, varscan2
- PRDM9 | c.1067G>T p.W356L | Missense Mutation (SNP) | VAF 368/1126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99691037; called by muse, mutect2, varscan2
- PRELP | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 120/461 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as COSV58116868; called by muse, mutect2, varscan2
- PREX2 | c.3592C>A p.Q1198K | Missense Mutation (SNP) | VAF 338/577 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV55788282; called by muse, mutect2, varscan2
- PRKCG | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 438/826 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV54730666; called by muse, mutect2, varscan2
- PROX1 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV54781545; called by muse, mutect2, varscan2
- PRRC2A | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 75/421 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as rs749972101, CM1515425; called by muse, mutect2, varscan2
- PRSS12 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 152/413 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367921225; called by muse, mutect2, varscan2
- PSG7 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230155441; called by muse, mutect2, varscan2
- PTGS2 | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 101/269 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV66570862; called by muse, mutect2
- PTPRN | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV55350470; called by muse, mutect2, varscan2
- PTPRQ | c.2181G>T p.K727N (on ENST00000616559; = p.K685N on NM_001145026.2) | Missense Mutation (SNP) | VAF 100/393 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV57047159; called by muse, mutect2, varscan2
- PTPRT | c.2690C>G p.P897R | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.242); catalogued as COSV100626267, COSV62002388, COSV62011706; called by muse, mutect2, varscan2
- PTPRZ1 | c.1555A>G p.T519A | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV66442034; called by muse, mutect2, varscan2
- PUDP | c.481A>G p.R161G | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV66904753; called by muse, mutect2, varscan2
- PYHIN1 | c.1403T>A p.F468Y | Missense Mutation (SNP) | VAF 186/532 reads (35%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.021); catalogued as COSV63731908; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1828A>G p.R610G | Missense Mutation (SNP) | VAF 57/556 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV62785900; called by muse, mutect2, varscan2
- RAB6A | c.452T>C p.M151T | Missense Mutation (SNP) | VAF 112/189 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1449431161, COSV60179299; called by muse, mutect2, varscan2
- RAD54L2 | c.3709G>T p.V1237L | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as rs1318865463, COSV56580355; called by muse, mutect2, varscan2
- RADX | c.1555T>A p.Y519N | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV65318027, COSV65319578; called by muse, mutect2, varscan2
- RASAL3 | c.2147C>T p.A716V | Missense Mutation (SNP) | VAF 96/174 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.236); catalogued as rs1175183908, COSV54606972, COSV54610212; called by muse, mutect2, varscan2
- RECK | c.2441G>A p.G814E | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.299); catalogued as COSV65035925; called by muse, mutect2, varscan2
- REG3G | c.511T>A p.C171S | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55450227, COSV55450731; called by muse, mutect2, varscan2
- RETNLB | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 77/640 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV55466019; called by muse, mutect2, varscan2
- RFX3 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 221/405 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV65862883; called by muse, mutect2, varscan2
- RGS21 | c.409G>C p.V137L | Missense Mutation (SNP) | VAF 41/494 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746901587, COSV69883312; called by muse, mutect2
- RIMS1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376314364, COSV99325307; called by muse, mutect2, varscan2
- RIMS1 | c.3817C>A p.Q1273K | Missense Mutation (SNP) | VAF 66/104 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV53471236; called by muse, mutect2, varscan2
- RIMS2 | c.838C>A p.H280N (on ENST00000666250 / NM_001348490.2; = p.H88N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 315/581 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.311); catalogued as COSV51704083; called by muse, mutect2, varscan2
- ROBO2 | c.3073C>T p.Q1025* | Nonsense Mutation (SNP) | VAF 130/322 reads (40%) | catalogued as COSV59895071; called by muse, varscan2
- RSKR | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 74/298 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV56382032, COSV56383106; called by muse, varscan2
- RSPO4 | c.297C>A p.F99L | Missense Mutation (SNP) | VAF 330/692 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54083088; called by muse, mutect2, varscan2
- RTL1 | c.1748G>T p.G583V | Missense Mutation (SNP) | VAF 243/368 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV66016458, COSV66017221; called by muse, mutect2, varscan2
- RTL1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 138/214 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV66017223; called by muse, mutect2, varscan2
- RYR2 | c.3746T>A p.M1249K | Missense Mutation (SNP) | VAF 101/552 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV63701132; called by muse, varscan2
- RYR2 | c.13058C>T p.P4353L | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as COSV63701139; called by muse, mutect2, varscan2
- RYR2 | c.13598T>C p.L4533P | Missense Mutation (SNP) | VAF 141/462 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs761272973, COSV63701148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.14144C>A p.T4715N | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63701160; called by muse, mutect2, varscan2
- SASH1 | c.2528T>G p.L843R | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV66563887; called by muse, mutect2, varscan2
- SAXO1 | c.1252G>T p.G418C | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV65871091; called by muse, mutect2, varscan2
- SCAMP3 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 97/431 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); catalogued as COSV56946682; called by muse, mutect2, varscan2
- SCAND1 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 59/268 reads (22%) | catalogued as rs1177786093, COSV60004893; called by muse, mutect2, varscan2
- SCLT1 | c.1059G>T p.E353D | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55410033; called by muse, mutect2, varscan2
- SCLY | c.688G>T p.A230S (on ENST00000651534; = p.A222S on NM_016510.7) | Missense Mutation (SNP) | VAF 81/220 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV54542968; called by muse, mutect2, varscan2
- SCRN1 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 107/953 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54132521; called by muse, mutect2, varscan2
- SEMA3C | c.2210A>G p.N737S | Missense Mutation (SNP) | VAF 67/494 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as rs775440476, COSV54852236; called by muse, mutect2, varscan2
- SEMA3C | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54852253; called by muse, mutect2, varscan2
- SEMA5A | c.3169G>T p.G1057W | Missense Mutation (SNP) | VAF 84/584 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV66800858; called by muse, mutect2, varscan2
- SERPINA3 | c.896G>C p.W299S | Missense Mutation (SNP) | VAF 104/504 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67585210, COSV67586727; called by muse, mutect2, varscan2
- SERPINB12 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54034292; called by muse, mutect2, varscan2
- SERPINB5 | c.861T>A p.C287* | Nonsense Mutation (SNP) | VAF 52/276 reads (19%) | catalogued as COSV66975852; called by muse, mutect2, varscan2
- SERPINB9 | c.569A>T p.E190V | Missense Mutation (SNP) | VAF 214/380 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV66233977; called by muse, mutect2, varscan2
- SGTA | c.828G>T p.A276= | Splice Region (SNP) | VAF 99/268 reads (37%) | catalogued as COSV55594847; called by muse, mutect2, varscan2
- SH2D7 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 129/225 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs756747596, COSV51949377; called by muse, mutect2, varscan2
- SH3TC2 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 220/301 reads (73%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60465999; called by muse, mutect2, varscan2
- SHOC1 | c.-23-2A>G | Splice Site (SNP) | VAF 44/87 reads (51%) | catalogued as rs375799601; called by muse, mutect2, varscan2
- SI | c.5188G>C p.E1730Q | Missense Mutation (SNP) | VAF 38/425 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV52290884; called by muse, mutect2
- SI | c.4507G>T p.A1503S | Missense Mutation (SNP) | VAF 137/492 reads (28%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.793); catalogued as COSV52290906; called by muse, mutect2, varscan2
- SIDT1 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 85/266 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV53504203, COSV99333725; called by muse, mutect2, varscan2
- SIN3A | c.1718G>T p.R573L | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV64581745, COSV64584116; called by muse, mutect2, varscan2
- SLC17A8 | c.1651A>G p.T551A | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs1220902779, COSV60125394; called by muse, mutect2, varscan2
- SLC1A3 | c.825C>A p.N275K | Missense Mutation (SNP) | VAF 117/467 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV54318632; called by muse, mutect2, varscan2
- SLC22A9 | c.1069A>G p.T357A | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV54168836; called by muse, mutect2, varscan2
- SLC24A2 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 250/497 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53870681; called by muse, mutect2, varscan2
- SLC28A3 | c.1811T>A p.M604K | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV66154297; called by muse, mutect2, varscan2
- SLC2A5 | c.1496C>G p.S499W | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV66236948, COSV66237535; called by muse, mutect2, varscan2
- SLC37A4 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs987244110, COSV58155855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC38A11 | c.156T>A p.Y52* | Nonsense Mutation (SNP) | VAF 78/238 reads (33%) | catalogued as COSV58055208; called by muse, mutect2, varscan2
- SLC6A1 | c.1603G>T p.G535C | Missense Mutation (SNP) | VAF 64/339 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV55117332; called by muse, mutect2, varscan2
- SLC8A2 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV52641521; called by muse, varscan2
- SLCO1A2 | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV56607065; called by muse, mutect2, varscan2
- SLFN13 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV53193028, COSV53194707; called by muse, mutect2, varscan2
- SLITRK1 | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 47/310 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV65676851; called by muse, mutect2, varscan2
- SMARCA2 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.186); catalogued as COSV61810282; called by muse, mutect2, varscan2
- SMARCD2 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 44/106 reads (42%) | catalogued as COSV56740956; called by muse, mutect2, varscan2
- SMG8 | c.2220G>C p.Q740H | Missense Mutation (SNP) | VAF 119/323 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56286400; called by muse, mutect2, varscan2
- SMOC1 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 257/362 reads (71%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.375); catalogued as rs767616965, COSV62762544; called by muse, mutect2, varscan2
- SNAPC4 | c.2453G>T p.R818M | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as COSV53735473; called by muse, mutect2, varscan2
- SNRNP200 | c.233G>C p.R78P | Missense Mutation (SNP) | VAF 218/503 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV60492564; called by muse, mutect2, varscan2
- SORCS1 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs777521482, COSV53888439; called by muse, mutect2, varscan2
- SOST | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 239/567 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.579); catalogued as COSV57013027; called by muse, mutect2, varscan2
- SOX6 | c.935T>A p.M312K | Missense Mutation (SNP) | VAF 286/565 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as COSV57052715; called by muse, varscan2
- SPAG16 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59109620; called by muse, mutect2, varscan2
- SPAST | c.1068A>C p.E356D | Missense Mutation (SNP) | VAF 164/638 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV59516149; called by muse, mutect2, varscan2
- SPATA17 | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 89/400 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV100860992, COSV65124719; called by muse, mutect2, varscan2
- SPATA31A6 | c.3228G>T p.R1076S | Missense Mutation (SNP) | VAF 421/911 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV100253571; called by muse, mutect2, varscan2
- SPEM1 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 61/79 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV57211200; called by muse, mutect2, varscan2
- SPPL2C | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61292841; called by muse, mutect2, varscan2
- SPTA1 | c.5471T>C p.F1824S | Missense Mutation (SNP) | VAF 84/972 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63756992; called by muse, mutect2
- SPTA1 | c.5041G>A p.V1681I | Missense Mutation (SNP) | VAF 353/916 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs371655531; called by muse, mutect2, varscan2
- SPTA1 | c.992C>G p.T331R | Missense Mutation (SNP) | VAF 193/857 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.158); catalogued as rs760769401, COSV63756995; called by muse, mutect2, varscan2
- SRL | c.642C>A p.F214L | Missense Mutation (SNP) | VAF 76/134 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV68423978; called by muse, varscan2
- SSRP1 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as COSV53480607; called by muse, mutect2, varscan2
- STIL | c.3310A>G p.T1104A | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as COSV54552146; called by muse, mutect2, varscan2
- STRA8 | c.133C>T p.Q45* (on ENST00000275764; = p.Q23* on NM_182489.2) | Nonsense Mutation (SNP) | VAF 127/318 reads (40%) | catalogued as COSV51962076; called by muse, mutect2, varscan2
- STX6 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 47/368 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV51113203; called by muse, mutect2, varscan2
- SUPT3H | c.721G>T p.A241S (on ENST00000371460 / NM_181356.3; = p.A230S on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/464 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV60945535; called by muse, mutect2, varscan2
- SV2A | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 32/517 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs200722955, COSV64964135, COSV64964693, COSV64965690; called by muse, mutect2
- SYNPO2 | c.1493G>T p.R498M | Missense Mutation (SNP) | VAF 78/458 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61114621; called by muse, mutect2, varscan2
- SZT2 | c.6291G>T p.R2097= (on ENST00000634258 / NM_001365999.1; = p.R2040= on NM_015284.4) | Splice Region (SNP) | VAF 86/256 reads (34%) | catalogued as COSV65172180; called by muse, mutect2, varscan2
- TAAR5 | c.481dup p.V161Gfs*38 | Frame Shift Ins (INS) | VAF 19/50 reads (38%) | catalogued as rs750163178; called by mutect2, pindel, varscan2
- TAFA4 | c.407C>A p.T136K | Missense Mutation (SNP) | VAF 160/353 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55142419; called by muse, mutect2, varscan2
- TAS2R39 | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV71470931; called by muse, mutect2, varscan2
- TBATA | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 27/339 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs566284389, COSV54720436; called by muse, mutect2
- TBC1D14 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.434); catalogued as COSV63391747; called by muse, mutect2, varscan2
- TBC1D22A | c.215G>T p.W72L | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV61442949; called by muse, mutect2, varscan2
- TBC1D30 | c.2431G>T p.D811Y (on ENST00000542120; = p.D648Y on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/306 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.438); catalogued as COSV57484265; called by muse, mutect2, varscan2
- TBC1D9 | c.273G>T p.W91C | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71308138; called by muse, mutect2, varscan2
- TBR1 | c.1216C>A p.R406S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV67418661; called by muse, mutect2, varscan2
- TCEAL2 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 94/179 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); catalogued as COSV61197571; called by muse, mutect2, varscan2
- TCF7L2 | c.625G>T p.E209* (on ENST00000355995 / NM_001367943.1; = p.E186* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 35/348 reads (10%) | catalogued as COSV53345283; called by muse, mutect2
- TCHH | c.5156A>T p.Q1719L | Missense Mutation (SNP) | VAF 328/1141 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV64276425; called by muse, mutect2, varscan2
- TCHHL1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV64286000; called by muse, mutect2, varscan2
- TCN2 | c.1234T>C p.Y412H | Missense Mutation (SNP) | VAF 170/489 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV53192309; called by muse, mutect2, varscan2
- TENM3 | c.7306T>C p.Y2436H | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV69314538; called by muse, mutect2, varscan2
- TENM4 | c.3513G>T p.W1171C | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53651928; called by muse, mutect2, varscan2
- TENM4 | c.3512G>T p.W1171L | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53651944, COSV99572927; called by muse, mutect2, varscan2
- TFPI | c.173C>A p.A58E | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV51903902, COSV51906042; called by muse, varscan2
- TG | c.2861G>T p.G954V | Missense Mutation (SNP) | VAF 221/1096 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV55082664, COSV55087403; called by muse, mutect2, varscan2
- TIGD5 | c.1422G>C p.E474D | Missense Mutation (SNP) | VAF 296/1091 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV55308147; called by muse, mutect2, varscan2
- TLR4 | c.550A>T p.S184C (on ENST00000355622 / NM_138554.5; = p.S144C on NM_003266.4) | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.732); catalogued as COSV62923847; called by muse, mutect2, varscan2
- TLR4 | c.2493C>A p.C831* (on ENST00000355622 / NM_138554.5; = p.C791* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 73/521 reads (14%) | catalogued as COSV62923850; called by muse, mutect2, varscan2
- TMEM132A | c.1121C>A p.P374Q (on ENST00000453848 / NM_178031.3; = p.P375Q on NM_017870.4) | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV50003890, COSV50014127; called by muse, mutect2, varscan2
- TMEM160 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV53409578; called by muse, mutect2, varscan2
- TMEM201 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777509881, COSV61052201; called by muse, varscan2
- TMEM63C | c.886T>A p.C296S | Missense Mutation (SNP) | VAF 235/358 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV53606324; called by muse, mutect2, varscan2
- TMEM63C | c.1218G>T p.W406C | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53606333; called by muse, mutect2, varscan2
- TMEM74 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 27/400 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52464120; called by muse, mutect2
- TMIE | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 197/904 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.763); catalogued as rs1341792536, COSV58406223; called by muse, mutect2, varscan2
- TMTC1 | c.1495A>T p.N499Y (on ENST00000539277 / NM_001193451.2; = p.N391Y on NM_175861.3) | Missense Mutation (SNP) | VAF 154/211 reads (73%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as COSV55488432; called by muse, mutect2, varscan2
- TMX4 | c.878G>C p.R293T | Missense Mutation (SNP) | VAF 48/558 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV55681760; called by muse, mutect2
- TNFRSF19 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50317143; called by muse, mutect2, varscan2
- TNS1 | c.4730A>G p.D1577G | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs1320416336, COSV50734820; called by muse, mutect2, varscan2
- TOP3B | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1465588241, COSV64118620; called by muse, mutect2, varscan2
- TOPAZ1 | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.055); catalogued as COSV59070606; called by muse, mutect2
- TPSG1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs1372674261, COSV52356702; called by muse, mutect2, varscan2
- TRARG1 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV61563052; called by muse, mutect2, varscan2
- TRBV30 | c.144del p.N49Tfs*45 | Frame Shift Del (DEL) | VAF 99/400 reads (25%) | catalogued as rs782317717; called by mutect2, pindel, varscan2
- TRIM21 | c.1172G>C p.G391A | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.487); catalogued as COSV54345360, COSV54346371; called by muse, mutect2, varscan2
- TRIM51 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 109/262 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV55265129; called by muse, mutect2, varscan2
- TRPM1 | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 330/486 reads (68%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV56638720; called by muse, mutect2, varscan2
- TRPM1 | c.2968C>A p.P990T | Missense Mutation (SNP) | VAF 151/223 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56638731, COSV56642233; called by muse, mutect2, varscan2
- TRPM3 | c.502C>A p.L168I (on ENST00000357533 / NM_001366142.2; = p.L13I on NM_020952.6) | Missense Mutation (SNP) | VAF 93/467 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV62467115, COSV62472408; called by muse, mutect2, varscan2
- TSPEAR | c.1869C>A p.Y623* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | catalogued as COSV59953643, COSV59972019; called by muse, mutect2, varscan2
- TSPOAP1 | c.4685G>A p.R1562Q | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs750069340; called by muse, mutect2, varscan2
- TTN | c.93064A>T p.T31022S (on ENST00000591111; = p.T23598S on NM_003319.4) | Missense Mutation (SNP) | VAF 53/130 reads (41%) | PolyPhen probably damaging (0.994); catalogued as COSV60216478, COSV60316592; called by muse, mutect2, varscan2
- TTN | c.89021C>A p.P29674H (on ENST00000591111; = p.P22250H on NM_003319.4) | Missense Mutation (SNP) | VAF 99/297 reads (33%) | PolyPhen probably damaging (0.988); catalogued as COSV60216512; called by muse, mutect2, varscan2
- TTN | c.65408C>A p.P21803H (on ENST00000591111; = p.P14379H on NM_003319.4) | Missense Mutation (SNP) | VAF 43/111 reads (39%) | PolyPhen probably damaging (0.961); catalogued as COSV60216599; called by muse, mutect2, varscan2
- TUBA4A | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 112/300 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50279949; called by muse, mutect2, varscan2
- TYK2 | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 303/393 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV53389741; called by muse, mutect2, varscan2
- UBA1 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 73/247 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60114296; called by muse, mutect2, varscan2
- UBR3 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as COSV55855881; called by muse, mutect2, varscan2
- UCK2 | c.327C>G p.I109M | Missense Mutation (SNP) | VAF 73/366 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs538874834, COSV63316254; called by muse, mutect2, varscan2
- UGT8 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 239/565 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100179074, COSV60419582; called by muse, mutect2, varscan2
- UMOD | c.1825G>T p.V609F | Missense Mutation (SNP) | VAF 196/407 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.395); catalogued as COSV56777966; called by muse, mutect2, varscan2
- UNC79 | c.4888G>A p.D1630N (on ENST00000393151 / NM_001346218.2; = p.D1453N on NM_020818.5) | Missense Mutation (SNP) | VAF 36/449 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs750647093, COSV56400562; called by muse, mutect2
- UNC80 | c.4680C>G p.Y1560* | Nonsense Mutation (SNP) | VAF 40/100 reads (40%) | catalogued as COSV55899665; called by muse, mutect2, varscan2
- UPF1 | c.3086G>T p.G1029V (on ENST00000599848 / NM_001297549.2; = p.G1018V on NM_002911.4) | Missense Mutation (SNP) | VAF 84/368 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV53199414; called by muse, mutect2, varscan2
- USH2A | c.13894C>A p.P4632T | Missense Mutation (SNP) | VAF 105/342 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56405603; called by muse, mutect2, varscan2
- USP31 | c.3326C>T p.S1109F | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV54854908; called by muse, mutect2, varscan2
- USP43 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV53305350; called by muse, mutect2, varscan2
- UTP14C | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 57/351 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV73000750; called by muse, mutect2, varscan2
- VIT | c.1420C>A p.L474M (on ENST00000389975 / NM_001177969.1; = p.L489M on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64898154; called by muse, mutect2, varscan2
- VPS13C | c.827A>T p.D276V (on ENST00000644861 / NM_020821.3; = p.D233V on NM_017684.5) | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as COSV51343429; called by muse, mutect2, varscan2
- VPS35L | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as rs1206685849, COSV51987609; called by muse, mutect2, varscan2
- VSIG8 | c.501C>A p.C167* | Nonsense Mutation (SNP) | VAF 164/439 reads (37%) | catalogued as COSV63653325, COSV63653596; called by muse, mutect2, varscan2
- VWA5B2 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV56613153; called by muse, mutect2, varscan2
- VWC2 | c.82A>T p.S28C | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); catalogued as COSV61482933, COSV61488755; called by muse, mutect2, varscan2
- VWCE | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 99/198 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57113919; called by muse, mutect2, varscan2
- WAS | c.663C>A p.S221R | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.496); catalogued as COSV64997493; called by muse, mutect2, varscan2
- WDR77 | c.450G>T p.K150N | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52385770, COSV52385858; called by muse, mutect2, varscan2
- WDR89 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 40/452 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV50827454; called by muse, mutect2
- XIRP2 | c.6292C>T p.P2098S (on ENST00000628543; = p.P2273S on NM_152381.6) | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs1283693560, COSV54695491, COSV54703881; called by muse, mutect2, varscan2
- XKR7 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 260/441 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73813340; called by muse, mutect2, varscan2
- XYLB | c.1504G>T p.A502S | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV52914837; called by muse, mutect2, varscan2
- XYLB | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1172961216, COSV52914849; called by muse, mutect2, varscan2
- ZBTB16 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 73/435 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV60097021; called by muse, mutect2, varscan2
- ZBTB49 | c.638A>G p.Y213C | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs572152212, COSV61925671; called by muse, mutect2, varscan2
- ZCCHC4 | c.967C>G p.R323G | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV57182562; called by muse, varscan2
- ZCRB1 | c.432A>C p.E144D | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV56891900; called by muse, mutect2, varscan2
- ZFHX4 | c.6306G>A p.M2102I | Missense Mutation (SNP) | VAF 140/486 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV51477983; called by muse, mutect2, varscan2
- ZFHX4 | c.7982G>T p.R2661M | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50725157, COSV51478022; called by muse, mutect2, varscan2
- ZFP42 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 194/435 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV58818459; called by muse, mutect2, varscan2
- ZFR2 | c.682G>T p.G228* | Nonsense Mutation (SNP) | VAF 67/158 reads (42%) | catalogued as COSV53601404; called by muse, mutect2
- ZGRF1 | c.4223G>C p.S1408T | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.067); catalogued as COSV71393546; called by muse, mutect2
- ZIC4 | c.880C>G p.P294A | Missense Mutation (SNP) | VAF 96/223 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.23); catalogued as COSV67173154; called by muse, mutect2, varscan2
- ZNF135 | c.964G>T p.G322C (on ENST00000313434 / NM_001289401.2; = p.G334C on NM_003436.4) | Missense Mutation (SNP) | VAF 108/386 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57884335; called by muse, mutect2, varscan2
- ZNF177 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 65/185 reads (35%) | catalogued as COSV58674194; called by muse, mutect2, varscan2
- ZNF318 | c.3368C>T p.P1123L | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV58935263; called by muse, mutect2
- ZNF33B | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63943020; called by muse, mutect2, varscan2
- ZNF420 | c.1821A>T p.R607S | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV58495367; called by muse, mutect2, varscan2
- ZNF439 | c.770A>C p.H257P | Missense Mutation (SNP) | VAF 111/197 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV58310339; called by muse, mutect2, varscan2
- ZNF441 | c.1189G>T p.G397W | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63540471; called by muse, mutect2, varscan2
- ZNF460 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 40/190 reads (21%) | catalogued as COSV64416088; called by muse, varscan2
- ZNF460 | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV64416093; called by muse, varscan2
- ZNF502 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 98/308 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV56074474; called by muse, mutect2, varscan2
- ZNF521 | c.3718C>A p.L1240I | Missense Mutation (SNP) | VAF 95/324 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV64129799; called by muse, mutect2, varscan2
- ZNF530 | c.1543A>T p.N515Y | Missense Mutation (SNP) | VAF 261/500 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV60532114; called by muse, mutect2, varscan2
- ZNF577 | c.371A>T p.D124V | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.278); catalogued as COSV56817056; called by muse, mutect2, varscan2
- ZNF595 | c.1918C>T p.R640* | Nonsense Mutation (SNP) | VAF 36/106 reads (34%) | catalogued as rs782667356; called by muse, mutect2, varscan2
- ZNF665 | c.125G>C p.G42A (on ENST00000600412; = p.G107A on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV67216475; called by muse, mutect2, varscan2
- ZNF675 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63096807; called by muse, mutect2, varscan2
- ZNF699 | c.1693G>T p.G565W | Missense Mutation (SNP) | VAF 191/245 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58026422; called by muse, mutect2, varscan2
- ZNF709 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV67195404; called by muse, mutect2, varscan2
- ZNF768 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 103/199 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs781378936, COSV53224390; called by muse, mutect2, varscan2
- ZNF99 | c.2283C>A p.C761* | Nonsense Mutation (SNP) | VAF 121/560 reads (22%) | catalogued as COSV68056423; called by muse, mutect2, varscan2
- ZSCAN9 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV52850532; called by muse, mutect2, varscan2
- ZYX | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs751760654, COSV51973752; called by muse, varscan2
- ABHD17A | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 175/398 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAD10 | c.1549_1594del p.D517Sfs*54 | Frame Shift Del (DEL) | VAF 126/234 reads (54%) | called by mutect2, pindel
- ADAMTS20 | c.5684_5685delinsT p.G1895Vfs*7 | Frame Shift Del (DEL) | VAF 25/204 reads (12%) | called by pindel, varscan2*
- ANK1 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 188/245 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ANKLE1 | c.1380C>A p.H460Q (on ENST00000394458; = p.H406Q on NM_152363.6) | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- ANKRD20A4P | c.1843G>T p.A615S | Missense Mutation (SNP) | VAF 214/1046 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, varscan2
- ANKRD27 | c.2768-2A>T p.X923_splice | Splice Site (SNP) | VAF 120/220 reads (55%) | called by muse, mutect2, varscan2
- ASB10 | c.1360C>A p.L454M (on ENST00000420175 / NM_001142459.2; = p.L439M on NM_080871.4) | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ATM | c.2124+2del p.X708_splice | Splice Site (DEL) | VAF 39/287 reads (14%) | called by mutect2, pindel, varscan2
- BRAP | c.82+4A>T | Splice Region (SNP) | VAF 26/126 reads (21%) | called by muse, mutect2
- C12orf43 | c.32del p.S11Wfs*56 | Frame Shift Del (DEL) | VAF 42/394 reads (11%) | called by mutect2, varscan2
- C4orf54 | c.2593C>A p.Q865K | Missense Mutation (SNP) | VAF 194/465 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- C8orf34 | c.802del p.R268Vfs*2 | Frame Shift Del (DEL) | VAF 56/316 reads (18%) | called by mutect2, pindel, varscan2
- CAMK1G | c.977G>A p.S326N | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- CASKIN1 | c.930+1G>A p.X310_splice | Splice Site (SNP) | VAF 38/178 reads (21%) | called by muse, mutect2, varscan2
- CBX4 | c.1522_1523insTGGCGG p.A507_A508insVA | In Frame Ins (INS) | VAF 16/124 reads (13%) | called by mutect2, pindel
- CCDC88C | c.3966+1G>T p.X1322_splice | Splice Site (SNP) | VAF 32/202 reads (16%) | called by muse, mutect2
- CFAP54 | c.3320G>T p.C1107F | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CIDEA | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- CRB1 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 70/882 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTAGE1 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 149/461 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- DBX1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- DESI2 | c.278del p.G93Efs*11 | Frame Shift Del (DEL) | VAF 34/352 reads (10%) | called by mutect2, pindel
- DGKK | c.2658-1G>T p.X886_splice | Splice Site (SNP) | VAF 115/139 reads (83%) | called by muse, mutect2, varscan2
- DPPA2 | c.789_790del p.L263Ffs*13 | Frame Shift Del (DEL) | VAF 103/250 reads (41%) | called by mutect2, pindel, varscan2
- DPYSL5 | c.1609+1G>T p.X537_splice | Splice Site (SNP) | VAF 91/179 reads (51%) | called by muse, mutect2, varscan2
- EGF | c.2647_2648del p.P883Cfs*29 | Frame Shift Del (DEL) | VAF 160/761 reads (21%) | called by mutect2, pindel, varscan2
- ERVV-1 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ERVV-2 | c.1570del p.Q524Kfs*32 | Frame Shift Del (DEL) | VAF 57/138 reads (41%) | called by mutect2, pindel
- FCGBP | c.6996C>G p.F2332L | Missense Mutation (SNP) | VAF 65/838 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.513); called by muse, mutect2
- FIBIN | c.305del p.S102Tfs*8 | Frame Shift Del (DEL) | VAF 38/82 reads (46%) | called by mutect2, pindel, varscan2
- FOLH1 | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 129/322 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR84 | c.433dup p.W145Lfs*27 | Frame Shift Ins (INS) | VAF 58/280 reads (21%) | called by mutect2, pindel, varscan2
- HDAC9 | c.528G>C p.W176C | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEATR1 | c.739del p.Q247Kfs*4 | Frame Shift Del (DEL) | VAF 80/274 reads (29%) | called by mutect2, pindel, varscan2
- HOXB1 | c.273del p.S92Afs*29 | Frame Shift Del (DEL) | VAF 83/410 reads (20%) | called by pindel, varscan2
- IFT88 | c.1327-1G>T p.X443_splice (on ENST00000319980 / NM_001318493.2; = p.X434_splice on NM_006531.5 and 9 other RefSeq transcripts) | Splice Site (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- IGKV1-33 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- IGLV2-11 | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IGSF1 | c.2485dup p.A829Gfs*15 | Frame Shift Ins (INS) | VAF 50/247 reads (20%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.279C>A p.Y93* | Nonsense Mutation (SNP) | VAF 102/402 reads (25%) | called by muse, mutect2, varscan2
- KRT10 | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 49/443 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.602); called by muse, varscan2
- KRT14 | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 132/295 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- KRTAP10-7 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 109/667 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- LPIN1 | c.93G>T p.M31I | Missense Mutation (SNP) | VAF 110/191 reads (58%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- LRATD2 | c.170_181del p.G57_P60del | In Frame Del (DEL) | VAF 418/744 reads (56%) | called by mutect2, pindel, varscan2
- LRCH2 | c.522del p.K174Nfs*28 | Frame Shift Del (DEL) | VAF 41/93 reads (44%) | called by mutect2, pindel, varscan2
- LRRC9 | c.3690C>A p.F1230L | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTB | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 98/189 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MAS1L | c.819C>G p.F273L | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MC2R | c.436del p.R146Afs*21 | Frame Shift Del (DEL) | VAF 96/334 reads (29%) | called by mutect2, pindel, varscan2
- MEGF6 | c.333_341del p.C111_G113del | In Frame Del (DEL) | VAF 29/119 reads (24%) | called by mutect2, pindel, varscan2
- MRC1 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 366/469 reads (78%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- MUC16 | c.41418G>C p.E13806D | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MUC16 | c.3068_3069del p.T1023Nfs*26 | Frame Shift Del (DEL) | VAF 128/256 reads (50%) | called by pindel, varscan2
- MUC19 | c.1050A>C p.T350= | Splice Region (SNP) | VAF 68/242 reads (28%) | called by muse, varscan2
- NBPF14 | c.3662G>A p.S1221N | Missense Mutation (SNP) | VAF 118/1208 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- NOTCH1 | c.1654T>C p.C552R | Missense Mutation (SNP) | VAF 105/399 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4Q3 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2
- PAK5 | c.1744-2A>T p.X582_splice | Splice Site (SNP) | VAF 174/335 reads (52%) | called by muse, mutect2, varscan2
- PASD1 | c.1313A>C p.H438P | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- PER2 | c.1937del p.G646Efs*2 | Frame Shift Del (DEL) | VAF 49/157 reads (31%) | called by mutect2, pindel, varscan2
378 further variants in this file (27 protein-altering or splice-affecting, 204 silent, 147 other) are not listed here.
